Somatic mutation profile of tumor specimen MMRF_1496_1_PB_CD138pos (aliquot MMRF_1496_1_PB_CD138pos_T2_KAS5U_L02465) from MMRF case MMRF_1496, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.9 years (14,564 days).
Specimen MMRF_1496_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce586476-ad2a-405b-9e6c-4ce4288a01c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1496_3_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1496_3_PB_CD3pos_C5_KBS5U_L06506; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f423a2fc-a105-4851-896c-1f0ae5906813

The open-access MAF lists 48 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 3'UTR 14, Silent 9, Nonsense Mutation 3, 5'UTR 2, 5'Flank 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 13/206 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AADACL2 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100735732; called by muse, mutect2, varscan2
- ARFGEF1 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51610018; called by muse, mutect2
- C2orf16 | c.4357C>T p.R1453* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as rs557771429, COSV62673324; called by muse, mutect2
- CFAP61 | c.2142G>C p.R714S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.28); catalogued as COSV55619190; called by muse, mutect2
- CYLD | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV61095154; called by muse, mutect2
- DHX57 | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs1207075515; called by muse, mutect2
- OR5AS1 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1244873387; called by muse, mutect2, varscan2
- POU4F3 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs539383335, COSV57942285; called by muse, mutect2
- RB1CC1 | c.3058del p.E1020Kfs*5 | Frame Shift Del (DEL) | VAF 37/267 reads (14%) | catalogued as COSV50265638; called by mutect2, pindel, varscan2
- SQSTM1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs118160361; called by muse, mutect2, varscan2
- ADCY2 | c.2670T>A p.F890L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.8496T>A p.F2832L (on ENST00000520002; = p.F2831L on NM_033225.6) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DYNC2H1 | c.3155A>G p.E1052G | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2
- MCF2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MYBBP1A | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PNPT1 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- STOX1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
- TRPM3 | c.2164C>A p.L722M (on ENST00000357533 / NM_001366142.2; = p.L565M on NM_020952.6) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCHSD1 | c.1407C>T p.L469= | Silent (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- LOXL4 | c.2223A>G p.A741= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- MID1 | c.195C>G p.L65= | Silent (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- MYO18B | c.2850G>A p.Q950= | Silent (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
- OR8J1 | c.123G>A p.G41= | Silent (SNP) | VAF 6/199 reads (3%) | catalogued as COSV57320059; called by muse, mutect2
- PDK2 | c.150C>T p.F50= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- SIX2 | c.771G>T p.V257= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- SLC26A1 | c.1170C>T p.L390= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99925680; called by muse, mutect2, varscan2
- TNRC18 | c.5127C>T p.F1709= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs760375574; called by muse, mutect2, varscan2
- APBA2 | c.*361C>T | 3'UTR (SNP) | VAF 39/183 reads (21%) | catalogued as rs930614687; called by muse, mutect2, varscan2
- ARHGAP36 | c.*433G>A | 3'UTR (SNP) | VAF 14/36 reads (39%) | catalogued as rs1474219883; called by muse, mutect2, varscan2
- BDP1 | c.*720C>T | 3'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.*510G>A | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.*408G>A | 3'UTR (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- NKX2-2 | c.*75T>C | 3'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- NLE1 | c.*489C>T | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- NSUN2 | chr5:6633105 G>A | 5'Flank (SNP) | VAF 42/74 reads (57%) | catalogued as rs530758742; called by muse, mutect2, varscan2
- NSUN2 | chr5:6633106 G>A | 5'Flank (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- PIK3CB | c.*1461C>T | 3'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as rs1268543208; called by muse, mutect2, varscan2
- PIP4P2 | c.*1726C>T | 3'UTR (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- PPIL1 | c.*775G>A | 3'UTR (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- RTL6 | c.*581T>C | 3'UTR (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- SESN3 | c.*7688C>T | 3'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- SLC39A8 | c.-21C>T | 5'UTR (SNP) | VAF 7/38 reads (18%) | catalogued as rs1560576299; called by mutect2, varscan2
- SYNRG | c.*988G>C | 3'UTR (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- TECR | c.16-19G>A | Intron (SNP) | VAF 7/97 reads (7%) | catalogued as rs1377984900; called by muse, mutect2
- WRAP53 | c.-507G>C | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- ZFP91 | c.*1405_*1410del | 3'UTR (DEL) | VAF 16/42 reads (38%) | called by mutect2, varscan2
